Somatic mutation profile of tumor specimen C3L-06933-01 (aliquot CPT0422570009) from CPTAC case C3L-06933, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.2 years (29,657 days).
Specimen C3L-06933-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80f302aa-0af6-4c04-ac7f-e53c2c99219f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06933-31 (Blood Derived Normal), aliquot CPT0422560003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad8a0991-c34e-4c9d-9e5a-4a3d79258cad

The open-access MAF lists 2,167 somatic variants for this specimen: 1,354 protein-altering or splice-affecting, 747 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,217, Silent 747, Nonsense Mutation 89, Intron 39, Splice Region 17, Frame Shift Del 14, Splice Site 11, 3'UTR 8, 5'Flank 7, 3'Flank 6, RNA 4, Translation Start Site 3.

Variants (750 of 2,167; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151107837, CM072855, COSV100778278; ClinVar: pathogenic; called by muse, mutect2
- BRAF | c.1526G>A p.G509E (on ENST00000288602 / NM_001374244.1; = p.G469E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 215/565 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 120/471 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 149/675 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs45442096, CM087591; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 112/520 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 219/444 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3952G>A p.G1318R | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59388433; called by muse, mutect2, varscan2
- AADAC | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs532572215, COSV51759323; called by muse, mutect2, varscan2
- ABCB5 | c.2259G>A p.Q753= (on ENST00000404938 / NM_001163941.2; = p.Q308= on NM_178559.6) | Splice Region (SNP) | VAF 156/330 reads (47%) | catalogued as rs769877561, COSV51722176; called by muse, mutect2, varscan2
- ABCC2 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100965642; called by muse, mutect2, varscan2
- ABCC3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 113/570 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752095627; called by muse, mutect2, varscan2
- AC011005.1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 135/524 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs1010384532; called by muse, mutect2
- AC011479.1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 124/703 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs532051981; called by muse, mutect2, varscan2
- ACAN | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 100/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61365382; called by muse, mutect2, varscan2
- ACTR6 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV51842385; called by muse, mutect2, varscan2
- ADAMTS10 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1555738275, COSV54353387; called by muse, mutect2, varscan2
- ADAMTS19 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176300; called by muse, mutect2, varscan2
- ADAMTS6 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.081); catalogued as COSV66861039; called by muse, mutect2, varscan2
- ADCY8 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 108/610 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs147685814, COSV53894976; called by muse, mutect2, varscan2
- ADGRE3 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53728863; called by muse, mutect2, varscan2
- ADGRL2 | c.4040G>A p.G1347E (on ENST00000370717 / NM_001366005.1; = p.G1291E on NM_012302.4) | Missense Mutation (SNP) | VAF 126/499 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs767448584; called by muse, mutect2, varscan2
- ADGRL4 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV66060148, COSV66061309; called by muse, mutect2, varscan2
- AGXT | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 83/351 reads (24%) | catalogued as COSV56755838; called by muse, mutect2, varscan2
- ALDH3A2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs150614683; called by muse, mutect2, varscan2
- ALG10B | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 76/483 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745701002, COSV100439978; called by muse, mutect2, varscan2
- ALK | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 219/555 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV66558174, COSV66563195; called by muse, mutect2, varscan2
- ALMS1 | c.4957C>T p.Q1653* | Nonsense Mutation (SNP) | VAF 134/563 reads (24%) | catalogued as COSV100042675; called by muse, mutect2, varscan2
- ALPG | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1402481883, COSV54965001; called by muse, mutect2, varscan2
- ALPK2 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 122/587 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV64490336; called by muse, mutect2, varscan2
- ANK1 | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 140/536 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV99227155; called by muse, mutect2, varscan2
- ANKEF1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs771848473, COSV65692003; called by muse, mutect2, varscan2
- ANKRD30A | c.1078G>A p.E360K (on ENST00000611781; = p.E304K on NM_052997.2) | Missense Mutation (SNP) | VAF 132/587 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77379875; called by muse, mutect2, varscan2
- APCS | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 124/484 reads (26%) | catalogued as rs775779605, COSV54819229; called by muse, mutect2, varscan2
- APOB | c.12432G>A p.W4144* | Nonsense Mutation (SNP) | VAF 220/572 reads (38%) | catalogued as rs867703004; called by muse, mutect2, varscan2
- APOB | c.10055C>T p.T3352I | Missense Mutation (SNP) | VAF 228/585 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs767624020, COSV51944878; called by muse, mutect2, varscan2
- APOBEC3F | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 110/500 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100415077; called by muse, mutect2, varscan2
- APOBR | c.2039G>A p.G680E (on ENST00000431282; = p.G689E on NM_018690.4) | Missense Mutation (SNP) | VAF 121/595 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV60493994; called by muse, mutect2, varscan2
- ARFGEF1 | c.3580C>T p.H1194Y | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99141292; called by muse, mutect2, varscan2
- ARFGEF2 | c.5225T>A p.I1742N | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV64213727; called by muse, mutect2, varscan2
- ARHGAP22 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV50937554; called by muse, mutect2, varscan2
- ARHGAP24 | c.733G>A p.G245S (on ENST00000395184 / NM_001025616.3; = p.G152S on NM_031305.3) | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138568771; called by muse, mutect2, varscan2
- ARHGEF17 | c.5846C>T p.S1949L | Missense Mutation (SNP) | VAF 156/682 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs764567023; called by muse, mutect2, varscan2
- ARHGEF5 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 35/596 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV50212784; called by muse, mutect2
- ARHGEF6 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 111/414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51693486; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ARVCF | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 116/584 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs761726212, COSV99599002; called by muse, mutect2, varscan2
- ASPDH | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 98/445 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs983100446; called by muse, mutect2, varscan2
- ATAD2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755251005, COSV54879444; called by muse, mutect2, varscan2
- ATG9A | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 111/548 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54698441; called by muse, mutect2, varscan2
- ATP10D | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV56713472; called by muse, mutect2, varscan2
- ATP1A2 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 103/536 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377054439; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100022862; called by muse, mutect2, varscan2
- ATP8B3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 96/592 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as rs1428651519; called by muse, mutect2, varscan2
- ATRX | c.4325C>T p.S1442F | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV64877722; called by muse, varscan2
- AXDND1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62640138; called by muse, mutect2, varscan2
- BAAT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 119/551 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773128969, COSV52287359; called by muse, mutect2, varscan2
- BANK1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1342122250, COSV59844441; called by muse, mutect2, varscan2
- BCL10 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65353906; called by muse, mutect2, varscan2
- BCLAF3 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61413189; called by muse, mutect2, varscan2
- BEST3 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770709086, COSV58302523; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 103/407 reads (25%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2
- BRINP1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs867838759, COSV99776846; called by muse, mutect2, varscan2
- BRPF1 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 89/504 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as rs777944933, COSV57351123; called by muse, mutect2, varscan2
- BRPF3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 104/536 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs771369726; called by muse, mutect2, varscan2
- BTN3A2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 79/783 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs764723723, COSV62687870; called by muse, mutect2, varscan2
- C10orf71 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 139/530 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1394571236; called by muse, mutect2, varscan2
- C22orf23 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 111/439 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs1235479347; called by muse, mutect2, varscan2
- C6 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV54710078; called by muse, varscan2
- C8A | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV63485640; called by muse, mutect2, varscan2
- C8B | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 93/536 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.516); catalogued as rs866295327, COSV64778442; called by muse, mutect2, varscan2
- C8orf74 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 117/618 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs923172574, COSV100262349, COSV100262420; called by muse, mutect2, varscan2
- C9 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54674942; called by muse, mutect2, varscan2
- CACNA1A | c.2837G>A p.S946N | Missense Mutation (SNP) | VAF 164/971 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.154); catalogued as rs1332420636, COSV64188691; called by muse, mutect2, varscan2
- CACNA1C | c.6212C>T p.P2071L (on ENST00000399634 / NM_001167625.1; = p.P2000L on NM_000719.7) | Missense Mutation (SNP) | VAF 164/537 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59717004; called by muse, mutect2, varscan2
- CACNA1E | c.3615G>A p.M1205I | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV62420617, COSV62432404; called by muse, varscan2
- CACNA1F | c.5480G>A p.R1827Q | Missense Mutation (SNP) | VAF 107/438 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs372426153, COSV59903951; called by muse, mutect2, varscan2
- CACNA1F | c.4930G>A p.E1644K | Missense Mutation (SNP) | VAF 121/557 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59902914; called by muse, mutect2, varscan2
- CACNA1I | c.5239G>A p.D1747N | Missense Mutation (SNP) | VAF 164/633 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs1374400440; called by muse, mutect2, varscan2
- CACNA2D1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752781035, COSV62384593; called by muse, mutect2, varscan2
- CAMTA1 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 37/621 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.207); catalogued as rs145242440; called by muse, mutect2
- CAPN6 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 138/549 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759303147, COSV60693828; called by muse, mutect2, varscan2
- CAPS2 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 68/273 reads (25%) | catalogued as rs557269709, COSV60823999; called by muse, mutect2, varscan2
- CARMIL3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 96/387 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1262227084; called by muse, mutect2, varscan2
- CATSPERE | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 103/448 reads (23%) | catalogued as rs1442164237, COSV63676392; called by muse, mutect2, varscan2
- CBFA2T2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1050504741, COSV60074811; called by muse, mutect2, varscan2
- CCDC114 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 57/386 reads (15%) | catalogued as COSV59555361; called by muse, mutect2, varscan2
- CCDC120 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 209/901 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs782180094; called by muse, mutect2, varscan2
- CCDC175 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1479054302; called by muse, varscan2
- CCDC70 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 135/553 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs746617980, COSV54431155; called by muse, mutect2, varscan2
- CCT8L2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 109/564 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV63461818; called by muse, mutect2, varscan2
- CD300LD | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 63/312 reads (20%) | catalogued as COSV64710290; called by muse, mutect2, varscan2
- CD34 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 134/568 reads (24%) | catalogued as rs753812536, COSV100178745; called by muse, mutect2, varscan2
- CDC27 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV50375857; called by muse, varscan2
- CDH18 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 130/562 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766286596, COSV56963540; called by muse, varscan2
- CDH18 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CDH9 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50304155, COSV99141430; called by muse, mutect2, varscan2
- CDHR3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs371586125, COSV100488412; called by muse, mutect2, varscan2
- CELSR1 | c.5473G>A p.G1825S | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as CM143047; called by muse, mutect2, varscan2
- CELSR1 | c.4108G>A p.D1370N | Missense Mutation (SNP) | VAF 139/660 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752297578; called by muse, mutect2, varscan2
- CELSR3 | c.8656C>T p.R2886* | Nonsense Mutation (SNP) | VAF 72/371 reads (19%) | catalogued as COSV99374883; called by muse, mutect2, varscan2
- CFAP100 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 164/423 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); catalogued as rs768300263; called by muse, mutect2, varscan2
- CFAP206 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51533370; called by mutect2, varscan2
- CFAP251 | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1427888977; called by muse, mutect2, varscan2
- CFAP54 | c.5266C>T p.Q1756* | Nonsense Mutation (SNP) | VAF 81/344 reads (24%) | catalogued as COSV61572371; called by muse, mutect2, varscan2
- CFAP57 | c.2680G>A p.G894R | Missense Mutation (SNP) | VAF 86/397 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs1451539350; called by muse, mutect2, varscan2
- CFAP74 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 91/388 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.508); catalogued as rs1485015765; called by muse, mutect2, varscan2
- CFHR2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66381166; called by muse, mutect2, varscan2
- CHMP4B | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 88/472 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1568612901, COSV54135915; called by muse, mutect2, varscan2
- CHRNE | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 97/506 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781565995; called by muse, mutect2, varscan2
- CHST13 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 221/699 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs748539742; called by muse, mutect2, varscan2
- CILP | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 149/679 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56026929; called by muse, mutect2, varscan2
- CLCN2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 93/457 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99658775; called by muse, mutect2, varscan2
- CLDN19 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs781067170, COSV56417150; called by muse, mutect2, varscan2
- CLIC5 | c.826G>A p.D276N (on ENST00000185206 / NM_001370649.1; = p.D117N on NM_016929.5) | Missense Mutation (SNP) | VAF 108/519 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV51757328; called by muse, mutect2, varscan2
- CLMN | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 108/552 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV54184675; called by muse, mutect2, varscan2
- CLMP | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 104/490 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs746344018; called by muse, mutect2, varscan2
- CLVS2 | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51569951; called by muse, mutect2, varscan2
- CNTNAP4 | c.3055C>T p.L1019F | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV100271576; called by muse, mutect2, varscan2
- CNTNAP5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867648836, COSV101443075; called by muse, mutect2, varscan2
- CNTNAP5 | c.3319C>T p.R1107* | Nonsense Mutation (SNP) | VAF 56/314 reads (18%) | catalogued as rs376033117; called by muse, mutect2, varscan2
- COBL | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 173/1053 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1382515420; called by muse, mutect2, varscan2
- COL11A1 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 103/312 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616020; called by muse, mutect2, varscan2
- COL11A2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 107/597 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1366378601; called by muse, mutect2, varscan2
- COL12A1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 106/361 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100485987; called by muse, mutect2, varscan2
- COL17A1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1452350309; called by muse, mutect2, varscan2
- COL3A1 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960331; called by muse, mutect2, varscan2
- COL4A5 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs778074923; called by muse, varscan2
- COL5A3 | c.3298G>A p.G1100R | Missense Mutation (SNP) | VAF 89/497 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770483332; called by muse, mutect2, varscan2
- COL5A3 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 136/391 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53412934; called by muse, mutect2, varscan2
- COL8A1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 122/651 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53729508; called by muse, mutect2, varscan2
- COL9A3 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 151/613 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV53896047; called by muse, mutect2, varscan2
- CORIN | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as COSV56686567; called by muse, mutect2, varscan2
- CPA4 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs1166564930; called by muse, mutect2, varscan2
- CPT1A | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1358714231; called by muse, mutect2, varscan2
- CR1 | c.3650C>T p.S1217L | Missense Mutation (SNP) | VAF 136/521 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV65461231; called by muse, mutect2, varscan2
- CREBRF | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 121/480 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.059); catalogued as COSV51636249; called by muse, mutect2, varscan2
- CRYBB2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 99/445 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs866268820, COSV68005292; called by muse, mutect2, varscan2
- CSMD1 | c.4220G>A p.S1407N (on ENST00000520002; = p.S1406N on NM_033225.6) | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs759772657; called by muse, mutect2, varscan2
- CSMD1 | c.1621G>A p.G541S (on ENST00000520002; = p.G540S on NM_033225.6) | Missense Mutation (SNP) | VAF 95/443 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59313264; called by muse, mutect2, varscan2
- CSMD1 | c.1297G>A p.E433K (on ENST00000520002; = p.E432K on NM_033225.6) | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV68163832; called by muse, mutect2, varscan2
- CSMD2 | c.9005G>A p.G3002E | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV53882695; called by muse, mutect2, varscan2
- CSMD2 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53946791, COSV99589705; called by muse, mutect2, varscan2
- CSMD2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV53914797; called by muse, mutect2, varscan2
- CSMD3 | c.2309C>T p.S770F (on ENST00000297405 / NM_001363185.1; = p.S666F on NM_052900.3) | Missense Mutation (SNP) | VAF 90/449 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV52229847, COSV52268030; called by muse, mutect2, varscan2
- CSMD3 | c.1466C>T p.P489L (on ENST00000297405 / NM_001363185.1; = p.P385L on NM_052900.3) | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52310331; called by muse, mutect2, varscan2
- CUBN | c.7648G>A p.D2550N | Missense Mutation (SNP) | VAF 94/476 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV64720202; called by muse, mutect2
- CUBN | c.6863C>T p.S2288L | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as rs778517256; called by muse, mutect2, varscan2
- CYLC2 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 119/475 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs746464948, COSV66336744; called by muse, mutect2, varscan2
- CYP4Z1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 111/507 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs1395744486; called by muse, mutect2, varscan2
- CYSLTR1 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 107/461 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs893499511, COSV64819691; called by muse, mutect2, varscan2
- DCAF4L2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 105/454 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.474); catalogued as rs368141152; called by muse, varscan2
- DCST2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 112/534 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55053031; called by muse, mutect2, varscan2
- DDX28 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs989668265; called by muse, mutect2, varscan2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2, varscan2
- DEFB112 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs867941522, COSV59182489; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 89/467 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DGKB | c.1686G>A p.W562* | Nonsense Mutation (SNP) | VAF 284/553 reads (51%) | catalogued as COSV51807976; called by muse, mutect2, varscan2
- DGKG | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 220/650 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752943537, COSV53962653; called by muse, mutect2, varscan2
- DGKG | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 108/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184020748; called by muse, mutect2, varscan2
- DLG5 | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 166/854 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs554975013; called by muse, mutect2, varscan2
- DMBT1 | c.6413G>A p.G2138E (on ENST00000338354 / NM_001377530.1; = p.G1381E on NM_004406.3) | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs747314121; called by muse, mutect2, varscan2
- DNAH10 | c.11935-1G>A p.X3979_splice (on ENST00000409039; = p.X3918_splice on NM_207437.3) | Splice Site (SNP) | VAF 91/436 reads (21%) | catalogued as rs1297485605; called by muse, mutect2, varscan2
- DNAH14 | c.4520G>A p.R1507Q (on ENST00000445597; = p.R1912Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775576952, COSV60736715; called by muse, mutect2, varscan2
- DNAH14 | c.6091G>A p.D2031N (on ENST00000445597; = p.D2684N on NM_001367479.1) | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV59904130; called by muse, mutect2, varscan2
- DNAH3 | c.2658G>A p.W886* | Nonsense Mutation (SNP) | VAF 71/350 reads (20%) | catalogued as rs1447273962; called by muse, mutect2, varscan2
- DNAH7 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 107/489 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV56781251; called by muse, mutect2, varscan2
- DNAH7 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766259116, COSV56768023; called by muse, mutect2, varscan2
- DNAH8 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs753499080, COSV100544351; called by muse, mutect2, varscan2
- DNAH8 | c.10261C>T p.P3421S | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953211968, COSV59447877; called by muse, mutect2, varscan2
- DNAJC25 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769661297, COSV57956685; called by muse, mutect2, varscan2
- DNTT | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs1477469177, COSV64522567; called by muse, mutect2, varscan2
- DOCK1 | c.3599C>T p.T1200I | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as COSV54729715; called by muse, mutect2, varscan2
- DOCK11 | c.3671G>A p.G1224E | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs1351482921; called by muse, mutect2, varscan2
- DOCK3 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 170/482 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1413025045, COSV99814143; called by muse, varscan2
- DOCK8 | c.3182C>T p.S1061F | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs754046747; called by muse, mutect2, varscan2
- DOP1B | c.3572C>T p.S1191L | Missense Mutation (SNP) | VAF 116/566 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201842098, COSV67692421; called by muse, mutect2, varscan2
- DPEP2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748950745, COSV99263260; called by muse, mutect2, varscan2
- DPEP3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 136/666 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1476940131, COSV52051231; called by muse, mutect2, varscan2
- DPYSL5 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 169/470 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs372829541; called by muse, mutect2, varscan2
- DSC2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 79/441 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760350556; called by muse, mutect2, varscan2
- DSC3 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100844554; called by muse, mutect2, varscan2
- DSC3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV64573382; called by muse, mutect2, varscan2
- DYSF | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs151109021, COSV99249763; called by muse, mutect2, varscan2
- DZIP1 | c.1513G>C p.E505Q (on ENST00000347108; = p.E486Q on NM_014934.5) | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as rs1423507960, COSV61267599; called by muse, mutect2, varscan2
- E2F7 | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs867819656; called by muse, mutect2, varscan2
- EFCAB5 | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs765040289; called by muse, mutect2, varscan2
- EFCAB6 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs748156231; called by muse, mutect2, varscan2
- EFCAB6 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV53072540; called by muse, mutect2, varscan2
- EFR3A | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 83/370 reads (22%) | catalogued as rs1332640689; called by muse, mutect2, varscan2
- EHD3 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 132/648 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.74); catalogued as rs777822714; called by muse, mutect2, varscan2
- ELF4 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 101/528 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as rs781193558; called by muse, mutect2, varscan2
- ELSPBP1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 76/314 reads (24%) | catalogued as rs767248894, COSV60413404; called by muse, varscan2
- EMSY | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 108/521 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1347469603; called by muse, mutect2, varscan2
- ENG | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 149/682 reads (22%) | catalogued as CM040740; called by muse, mutect2, varscan2
- EOLA1 | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 107/578 reads (19%) | catalogued as rs1396090339; called by muse, mutect2, varscan2
- ERAP2 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 119/519 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs774338095; called by muse, mutect2, varscan2
- ERG | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 83/410 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV55728545; called by muse, mutect2, varscan2
- ERN2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1039118755, COSV56836130; called by muse, mutect2, varscan2
- ESYT2 | c.2179C>T p.P727S (on ENST00000613624; = p.P651S on NM_020728.3) | Missense Mutation (SNP) | VAF 170/665 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as COSV51757205; called by muse, mutect2, varscan2
- EXTL3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 91/575 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs753235953; called by muse, mutect2, varscan2
- EYS | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV65491910; called by muse, mutect2, varscan2
- F13A1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 112/518 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166766083; called by muse, mutect2, varscan2
- F2R | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 145/582 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100058727; called by muse, mutect2, varscan2
- F5 | c.4861C>T p.R1621* | Nonsense Mutation (SNP) | VAF 80/380 reads (21%) | catalogued as COSV63128804; called by muse, mutect2, varscan2
- F8 | c.5590A>G p.K1864E | Missense Mutation (SNP) | VAF 95/429 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as CM990557; called by muse, mutect2, varscan2
- FAM135B | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99422403; called by muse, mutect2, varscan2
- FAM166A | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 109/508 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs761314868; called by muse, mutect2, varscan2
- FAM186A | c.5903T>C p.L1968S | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs760870643; called by muse, mutect2, varscan2
- FAM220A | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 105/719 reads (15%) | catalogued as COSV57625848; called by muse, mutect2, varscan2
- FANCM | c.3610C>T p.R1204C | Missense Mutation (SNP) | VAF 106/399 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs763796272, COSV57503555; called by muse, mutect2, varscan2
- FAT3 | c.8024C>T p.S2675L | Missense Mutation (SNP) | VAF 103/416 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53094091, COSV53094990; called by muse, mutect2, varscan2
- FAT4 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766427266, COSV58670665; called by muse, mutect2, varscan2
- FBLN1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs772445995, COSV53044161, COSV53049144; called by muse, mutect2, varscan2
- FBXL7 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 97/458 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs778729469, COSV61648143; called by muse, mutect2, varscan2
- FBXL7 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 105/526 reads (20%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.461); catalogued as COSV61653895; called by muse, mutect2, varscan2
- FBXO38 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764491940, COSV57029286; called by muse, mutect2, varscan2
- FBXO40 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 100/590 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748396801, COSV57522667; called by muse, mutect2, varscan2
- FBXW10 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1410185429, COSV100111744, COSV57316985; called by muse, mutect2, varscan2
- FCRL1 | c.412A>C p.M138L | Missense Mutation (SNP) | VAF 96/429 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63826586; called by mutect2, varscan2
- FCRL3 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 93/466 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.034); catalogued as rs756620692; called by muse, mutect2, varscan2
- FER1L6 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1340145911; called by muse, varscan2
- FGF5 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100427842; called by muse, mutect2, varscan2
- FIBIN | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 152/589 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as rs1221687056, COSV59413821; called by muse, mutect2, varscan2
- FLG | c.11278G>A p.G3760R | Missense Mutation (SNP) | VAF 150/754 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1401998194; called by muse, mutect2, varscan2
- FLG | c.8498G>A p.G2833E | Missense Mutation (SNP) | VAF 127/1312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1401517481, COSV64246918; called by muse, mutect2, varscan2
- FLT3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs866313760; called by muse, mutect2, varscan2
- FMNL1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 103/417 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as rs1207365920, COSV58957054; called by muse, mutect2, varscan2
- FMNL2 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99979420; called by muse, mutect2, varscan2
- FOLH1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267602925, COSV57045271; called by muse, mutect2, varscan2
- FOXJ1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 172/727 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764131474; called by muse, mutect2, varscan2
- FSCB | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 100/477 reads (21%) | catalogued as COSV100469332, COSV61218576; called by muse, mutect2, varscan2
- FSTL5 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1195901638; called by muse, mutect2, varscan2
- FTCD | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 142/608 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs749329384; called by muse, mutect2, varscan2
- FTMT | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 143/576 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs758300439, COSV58420399; called by muse, mutect2, varscan2
- G2E3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs997578937, COSV52838478; called by muse, mutect2, varscan2
- GAB4 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV68753065; called by muse, mutect2, varscan2
- GABRA3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1228855985, COSV64798895, COSV64800358; called by muse, mutect2, varscan2
- GABRB1 | c.1247G>C p.R416P | Missense Mutation (SNP) | VAF 149/508 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.331); catalogued as COSV54970002; called by muse, mutect2, varscan2
- GABRG3 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.439); catalogued as COSV61509236; called by muse, mutect2, varscan2
- GALNTL5 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs762776047, COSV67179244; called by muse, mutect2, varscan2
- GATA2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 146/707 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs778562222, COSV62006398; called by muse, mutect2, varscan2
- GBF1 | c.4384C>T p.R1462W (on ENST00000369983 / NM_001377137.1; = p.R1461W on NM_004193.3) | Missense Mutation (SNP) | VAF 115/549 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1462360035; called by muse, mutect2, varscan2
- GCKR | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 202/536 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs765340729, COSV53107303; called by muse, mutect2, varscan2
- GDF3 | c.588A>T p.K196N | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV61712447; called by mutect2, varscan2
- GEM | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 151/591 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs375369112; called by muse, mutect2, varscan2
- GLUD2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 149/738 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100046724; called by muse, varscan2
- GLYATL3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225939229, COSV64592784; called by muse, varscan2
- GNG7 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 91/521 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs375210035; called by muse, varscan2
- GPR137B | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777123792, COSV63991523; called by muse, mutect2, varscan2
- GPR15 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 108/535 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs1370892290; called by muse, mutect2, varscan2
- GPR158 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200936444, COSV66265992; called by muse, mutect2, varscan2
- GPR158 | c.3424A>G p.K1142E | Missense Mutation (SNP) | VAF 104/472 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100893424; called by muse, mutect2, varscan2
- GPR68 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 121/622 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780038976, COSV99473615; called by muse, mutect2, varscan2
- GPX2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 117/498 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs780148112, COSV50824933, COSV99962239; called by muse, mutect2, varscan2
- GRIA3 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 120/495 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs746285416; called by muse, mutect2, varscan2
- GRIA3 | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV99988611; called by muse, mutect2, varscan2
- GRIK1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199185678; called by muse, mutect2, varscan2
- GRIN3A | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100701825; called by muse, mutect2, varscan2
- GRIP1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54037044; called by muse, mutect2, varscan2
- GTF3C2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 214/563 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs768291859; called by muse, varscan2
- GTPBP8 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 98/432 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs747168489; called by muse, mutect2, varscan2
- H2BW2 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 157/812 reads (19%) | catalogued as rs1465169840; called by muse, mutect2, varscan2
- HAL | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV54118360; called by muse, mutect2, varscan2
- HCN3 | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 210/984 reads (21%) | catalogued as rs1369150652; called by muse, mutect2, varscan2
- HGF | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55950930, COSV55951004; called by muse, mutect2, varscan2
- HID1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); catalogued as rs370760336; called by muse, mutect2, varscan2
- HIPK3 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 101/401 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs748722092; called by muse, mutect2, varscan2
- HK2 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 90/415 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1455796627; called by muse, mutect2, varscan2
- HRNR | c.5420G>A p.G1807D | Missense Mutation (SNP) | VAF 53/796 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as rs1350247025; called by muse, mutect2, varscan2
- HTN1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.006); catalogued as COSV99887487; called by muse, mutect2, varscan2
- HTR6 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 134/567 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197300204, COSV99230181; called by muse, mutect2, varscan2
- HUWE1 | c.8477C>T p.S2826F | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53339214; called by muse, mutect2, varscan2
- HYDIN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs866201822, COSV55478832; called by muse, mutect2, varscan2
- IDS | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs868956857; called by muse, varscan2
- IGFN1 | c.2912C>T p.S971F (on ENST00000295591 / NM_001367841.1; = p.S3428F on NM_001164586.2) | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1302041998; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 86/639 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs779308098; called by muse, mutect2
- IGKV3-11 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 156/636 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs549340494; called by muse, mutect2, varscan2
- IGKV3-20 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 110/584 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1254239989; called by muse, mutect2, varscan2
- IGLV1-44 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 99/458 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.029); catalogued as rs1341746571; called by muse, mutect2, varscan2
- IGSF10 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 116/669 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs761343862; called by muse, mutect2, varscan2
- IGSF9B | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 146/684 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750701608; called by muse, varscan2
- IKZF1 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs758404349; called by muse, mutect2, varscan2
- IKZF1 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 153/369 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs780268193; called by muse, mutect2, varscan2
- IKZF2 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563781, COSV100563803; called by muse, mutect2, varscan2
- IKZF2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 138/621 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs768257175, COSV59581913; called by muse, mutect2, varscan2
- IL17RB | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs749449007, COSV55474487; called by muse, mutect2, varscan2
- IL2RB | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1489428622; called by muse, mutect2, varscan2
- INCA1 | c.335G>A p.R112Q (on ENST00000574617 / NM_001167986.1; = p.R97Q on NM_213726.2) | Missense Mutation (SNP) | VAF 277/714 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs750197169, COSV61788845; called by muse, mutect2, varscan2
- INMT | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 397/801 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as COSV50000136; called by muse, mutect2, varscan2
- IQCH | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144463314; called by muse, mutect2, varscan2
- IRF2BP2 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV64015592; called by muse, mutect2, varscan2
- ITGA3 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 111/493 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs267604940; called by muse, mutect2, varscan2
- ITGA5 | c.691+1G>A p.X231_splice | Splice Site (SNP) | VAF 75/358 reads (21%) | catalogued as rs1219092600; called by muse, mutect2, varscan2
- ITGBL1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs761666432; called by muse, mutect2, varscan2
- ITPR1 | c.4781C>T p.S1594F (on ENST00000354582; = p.S1579F on NM_002222.7) | Missense Mutation (SNP) | VAF 167/445 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV100230711; called by muse, mutect2, varscan2
- KANK4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs753716013, COSV62986172; called by muse, mutect2, varscan2
- KCNB1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 122/503 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65565845, COSV65571021; called by muse, mutect2, varscan2
- KCNB1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 129/598 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65569828; called by muse, mutect2, varscan2
- KCNJ6 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55719817; called by muse, mutect2, varscan2
- KCNQ2 | c.2138C>T p.P713L (on ENST00000359125 / NM_172107.4; = p.P685L on NM_004518.6) | Missense Mutation (SNP) | VAF 177/797 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs750333438, COSV60545260; called by muse, mutect2, varscan2
- KCNU1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1320764612; called by muse, mutect2, varscan2
- KIAA0232 | c.3785C>T p.S1262L | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.995); catalogued as rs369418898; called by muse, mutect2, varscan2
- KIAA0513 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV50741651; called by muse, mutect2, varscan2
- KIAA1549 | c.5098C>T p.P1700S | Missense Mutation (SNP) | VAF 129/684 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757022718; called by muse, mutect2, varscan2
- KIF13B | c.3875G>A p.R1292Q | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); catalogued as rs749611889, COSV72954704; called by muse, mutect2, varscan2
- KIF26B | c.4305G>A p.M1435I | Missense Mutation (SNP) | VAF 196/756 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1391303578; called by muse, mutect2, varscan2
- KLKB1 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs150832692; called by muse, mutect2, varscan2
- KRT13 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 94/417 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55840520; called by muse, mutect2, varscan2
- KRT2 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 173/685 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs761268576, COSV59012387; called by muse, mutect2, varscan2
- KRT75 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 75/497 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs865992888, COSV99359450; called by muse, mutect2, varscan2
- KRTAP10-5 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 167/730 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1334431224; called by muse, mutect2, varscan2
- KSR2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 101/432 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV56685293; called by muse, mutect2, varscan2
- KTI12 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 122/488 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV65405814; called by muse, mutect2, varscan2
- KY | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 223/596 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV71017668; called by muse, mutect2, varscan2
- L1TD1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.211); catalogued as rs1018946511; called by muse, mutect2, varscan2
- LAMA5 | c.3677C>T p.P1226L | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1270215486; called by muse, mutect2, varscan2
- LCE1E | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 178/848 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV64220000; called by muse, mutect2
- LCP2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs779018199; called by muse, mutect2, varscan2
- LCT | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as rs1326579339; called by muse, mutect2, varscan2
- LEFTY2 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 120/682 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64746924; called by muse, mutect2, varscan2
- LGSN | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV65726718; called by muse, mutect2, varscan2
- LILRA1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV52186190; called by muse, varscan2
- LILRA4 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as rs759029664; called by muse, mutect2, varscan2
- LILRB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 137/606 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV54406647; called by muse, mutect2
- LIPI | c.710del p.L237* | Frame Shift Del (DEL) | VAF 46/262 reads (18%) | catalogued as COSV60714374; called by mutect2, pindel, varscan2
- LIPK | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.042); catalogued as rs760205361; called by muse, mutect2, varscan2
- LMX1B | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 139/608 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.649); catalogued as rs373336352; called by muse, mutect2, varscan2
- LOXHD1 | c.4243C>T p.R1415W | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1470715466; called by muse, mutect2, varscan2
- LPAR1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 151/547 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs1199624602, COSV62687565; called by muse, mutect2, varscan2
- LRCH3 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 145/339 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774188178; called by muse, mutect2, varscan2
- LRP1B | c.6925G>A p.E2309K | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs1217576638, COSV67281725; called by muse, mutect2, varscan2
- LRP2 | c.13570C>T p.P4524S | Missense Mutation (SNP) | VAF 105/417 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340675692, COSV99787719; called by muse, mutect2, varscan2
- LRRC4C | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 101/502 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs866935822; called by muse, mutect2, varscan2
- LRRC7 | c.1570G>A p.E524K (on ENST00000651989 / NM_001370785.2; = p.E491K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs866086728, COSV50412443; called by muse, mutect2, varscan2
- LRRIQ4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 119/682 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100540268; called by muse, mutect2, varscan2
- LRRN1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 118/643 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100075962; called by muse, mutect2, varscan2
- LTA | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 182/801 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1281458106; called by muse, varscan2
- LTF | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 92/535 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs146006710; called by muse, mutect2, varscan2
- LY96 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs868086563, COSV99514528; called by muse, mutect2, varscan2
- MACROD2 | c.1145-1G>A p.X382_splice (on ENST00000642719; = p.X354_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 49/249 reads (20%) | catalogued as COSV53946838, COSV54005874, COSV99428277; called by muse, mutect2, varscan2
- MAGEA10 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV54884189, COSV99726826; called by muse, varscan2
- MAGEA6 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 138/648 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100262721; called by muse, mutect2, varscan2
- MAGEB6 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 184/818 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746031016, COSV66872309; called by muse, mutect2, varscan2
- MAGEC1 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 126/620 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV53568039; called by muse, mutect2, varscan2
- MAGEC1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 184/725 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.641); catalogued as rs749947117; called by muse, mutect2, varscan2
- MAGED1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58514999; called by muse, mutect2, varscan2
- MAGEL2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 190/946 reads (20%) | SIFT tolerated, low confidence (0.14); catalogued as COSV58568542; called by muse, mutect2, varscan2
- MALRD1 | c.3749C>T p.S1250F | Missense Mutation (SNP) | VAF 86/391 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66005773; called by muse, mutect2, varscan2
- MAPK3 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 114/581 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750160678, COSV53774927; called by muse, mutect2, varscan2
- MARCO | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 104/599 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1394987980, COSV59053641; called by muse, mutect2, varscan2
- MAST4 | c.7685G>A p.G2562E (on ENST00000403625 / NM_001164664.2; = p.G2373E on NM_015183.3) | Missense Mutation (SNP) | VAF 146/609 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as rs1347855057; called by muse, mutect2, varscan2
- MCF2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535630790; called by muse, mutect2, varscan2
- MECOM | c.1900C>T p.P634S (on ENST00000468789 / NM_001105078.4; = p.P822S on NM_004991.4) | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52965270; called by muse, mutect2, varscan2
- MECOM | c.1216G>A p.E406K (on ENST00000468789 / NM_001105078.4; = p.E594K on NM_004991.4) | Missense Mutation (SNP) | VAF 116/640 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99244487; called by muse, mutect2, varscan2
- MEGF8 | c.2713C>T p.R905W (on ENST00000251268 / NM_001271938.2; = p.R838W on NM_001410.3) | Missense Mutation (SNP) | VAF 132/572 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs375529059; called by muse, mutect2, varscan2
- MET | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 162/573 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV59258667; called by muse, mutect2, varscan2
- MFSD2B | c.549C>T p.Y183= | Splice Region (SNP) | VAF 206/539 reads (38%) | catalogued as rs1409942448; called by muse, mutect2, varscan2
- MFSD2B | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 203/532 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775176336; called by muse, mutect2, varscan2
- MIPEP | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV66301692; called by muse, mutect2, varscan2
- MMP27 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52780383; called by muse, mutect2, varscan2
- MOBP | c.527C>T p.P176L (on ENST00000420739; = p.P200L on NM_001278322.2) | Missense Mutation (SNP) | VAF 114/704 reads (16%) | PolyPhen probably damaging (0.991); catalogued as rs533785650; called by muse, mutect2, varscan2
- MORC1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138435095, COSV51713000; called by muse, mutect2, varscan2
- MORC1 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV51715179, COSV51721971; called by muse, mutect2, varscan2
- MPP7 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV61732529; called by muse, mutect2, varscan2
- MPZL1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 63/322 reads (20%) | catalogued as COSV63256187; called by muse, mutect2, varscan2
- MRI1 | c.1079G>A p.R360K (on ENST00000040663 / NM_001031727.4; = p.R313K on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 222/618 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99237884; called by muse, mutect2, varscan2
- MSANTD1 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 142/515 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs762000124, COSV104437218; called by muse, mutect2, varscan2
- MST1R | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 263/633 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56572991; called by muse, mutect2, varscan2
- MUC16 | c.36539C>T p.T12180I | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.218); catalogued as rs765525874; called by muse, mutect2, varscan2
- MUC16 | c.24803C>T p.S8268F | Missense Mutation (SNP) | VAF 117/558 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1330676451, COSV67461695; called by muse, mutect2, varscan2
- MUC16 | c.19321G>A p.E6441K | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs754686482, COSV101198402, COSV67442701; called by muse, mutect2, varscan2
- MUC16 | c.13678G>A p.E4560K | Missense Mutation (SNP) | VAF 91/614 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as rs1467475602; called by muse, mutect2, varscan2
- MUC16 | c.12883G>A p.E4295K | Missense Mutation (SNP) | VAF 100/528 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs866967106, COSV67470836; called by muse, mutect2, varscan2
- MUC16 | c.5410G>A p.E1804K | Missense Mutation (SNP) | VAF 95/576 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV67471874; called by muse, mutect2, varscan2
- MUC17 | c.5873C>T p.T1958I | Missense Mutation (SNP) | VAF 127/645 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs763909919, COSV60287297, COSV60295118; called by muse, mutect2, varscan2
- MUC4 | c.5449G>A p.A1817T | Missense Mutation (SNP) | VAF 151/1836 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.494); catalogued as rs1171761262; called by muse, mutect2
- MUSK | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 76/329 reads (23%) | catalogued as rs751003770; called by muse, mutect2, varscan2
- MYH14 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747770727, COSV51809763; called by muse, mutect2, varscan2
- MYH2 | c.4025C>T p.S1342F | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs267604721, COSV55431454; called by muse, mutect2, varscan2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- MYO18B | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 124/590 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs1339564822, COSV59131979; called by muse, varscan2
- MYO18B | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 110/530 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1483035499; called by muse, varscan2
- MYO18B | c.3289G>A p.D1097N | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.465); catalogued as rs753957467, COSV59130072; called by muse, mutect2, varscan2
- MYO1A | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267603596; called by muse, mutect2, varscan2
- MYO5B | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs750970018; called by muse, mutect2, varscan2
- MYT1L | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 221/598 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as rs772139854, COSV67710183; called by muse, mutect2, varscan2
- N4BP2 | c.4379C>T p.S1460L | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV54701206; called by muse, mutect2, varscan2
- NALCN | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs780641051, COSV51936196; called by muse, mutect2, varscan2
- NARS2 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55250807; called by muse, mutect2, varscan2
- NCAM1 | c.2072G>A p.G691E (on ENST00000316851 / NM_181351.5; = p.G681E on NM_000615.7) | Missense Mutation (SNP) | VAF 113/512 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57510911; called by muse, mutect2, varscan2
- NCAM1 | c.2534C>T p.P845L (on ENST00000316851 / NM_181351.5; = p.P835L on NM_000615.7) | Missense Mutation (SNP) | VAF 93/486 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs782756992, COSV57511297; called by muse, mutect2, varscan2
- NCF2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759940920, COSV62314830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5 | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58429133; called by muse, mutect2, varscan2
- NEB | c.10651C>T p.H3551Y | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51460793, COSV99428042; called by muse, mutect2, varscan2
- NEBL | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV65801669; called by muse, mutect2, varscan2
- NEXMIF | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 150/715 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs755362755; called by muse, mutect2, varscan2
- NLRP13 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV61623768; called by muse, mutect2, varscan2
- NLRP5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs780828462, COSV66763274, COSV66766342; called by muse, mutect2, varscan2
- NOC4L | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 55/316 reads (17%) | catalogued as rs768448816, COSV100222960; called by muse, mutect2, varscan2
- NOL10 | c.1708C>G p.Q570E | Missense Mutation (SNP) | VAF 89/461 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1182484456; called by muse, mutect2, varscan2
- NOTCH4 | c.5944C>G p.Q1982E | Missense Mutation (SNP) | VAF 171/874 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs577160458, COSV66683978; called by muse, mutect2, varscan2
- NPFFR1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 150/619 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs1203396492, COSV53335417; called by muse, mutect2, varscan2
- NPIPB15 | c.546G>A p.Q182= | Splice Region (SNP) | VAF 40/642 reads (6%) | catalogued as COSV101466037; called by muse, mutect2
- NRIP1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs765110771; called by muse, mutect2, varscan2
- NSMCE4A | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 54/273 reads (20%) | catalogued as COSV100940064, COSV100940078; called by muse, mutect2, varscan2
- NTM | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 149/583 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779050882, COSV66178975; called by muse, mutect2, varscan2
- OBP2B | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64402161; called by muse, mutect2, varscan2
- OBSCN | c.13132G>A p.E4378K | Missense Mutation (SNP) | VAF 156/657 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs773247093, COSV52785007; called by muse, mutect2, varscan2
- OR10G7 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 113/590 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs752771848, COSV100390114; called by muse, mutect2, varscan2
- OR10H3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 118/629 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV59944818; called by muse, mutect2, varscan2
- OR10V1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.059); catalogued as rs758226739; called by muse, mutect2, varscan2
- OR11H6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 116/475 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs367798181; called by muse, mutect2
- OR2AK2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV63556704; called by muse, mutect2, varscan2
- OR2AP1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV58725491, COSV58726630; called by muse, mutect2, varscan2
- OR2L2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV63553622; called by muse, mutect2, varscan2
- OR3A3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs749859849; called by muse, mutect2, varscan2
- OR4C5 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 110/482 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs1287637562; called by muse, varscan2
- OR4C6 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 128/554 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100051905, COSV58602729; called by muse, mutect2, varscan2
- OR4K13 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs202203700, COSV59859121; called by muse, mutect2, varscan2
- OR4L1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 98/412 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs369912800; called by muse, mutect2, varscan2
- OR4N2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 147/682 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60050111; called by muse, mutect2, varscan2
- OR4S2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV56748425; called by muse, mutect2, varscan2
- OR51F2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 91/465 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59063872; called by muse, mutect2, varscan2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR51I2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 89/344 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244327018, COSV58299534; called by muse, mutect2, varscan2
- OR51M1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 137/547 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs748174844; called by muse, mutect2, varscan2
- OR56B1 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 75/393 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs370914437; called by muse, mutect2, varscan2
- OR5B12 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV56905808; called by muse, mutect2, varscan2
- OR5I1 | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.994); catalogued as COSV56889322; called by muse, mutect2, varscan2
- OR5R1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 142/577 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV56571496; called by muse, mutect2, varscan2
- OR6C65 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV65568097; called by muse, varscan2
- OR6K6 | c.731C>T p.S244F (on ENST00000368144; = p.S220F on NM_001005184.1) | Missense Mutation (SNP) | VAF 126/582 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63744007; called by muse, mutect2, varscan2
- OR8S1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 133/543 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as rs150212885; called by muse, mutect2, varscan2
- OR9A4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 114/505 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV71884912; called by muse, mutect2, varscan2
- OTOG | c.7302C>T p.C2434= | Splice Region (SNP) | VAF 103/440 reads (23%) | catalogued as rs1450427701; called by muse, mutect2, varscan2
- OXA1L | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.025); catalogued as rs866495733, COSV53537277; called by muse, mutect2, varscan2
- PANX3 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 135/563 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.621); catalogued as COSV99421667; called by muse, mutect2, varscan2
- PAPOLB | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 102/694 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.349); catalogued as rs867228239, COSV68199333; called by muse, mutect2, varscan2
- PARP8 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 98/468 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55862168; called by muse, mutect2, varscan2
- PARS2 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 164/607 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs755649256, COSV64883735; called by muse, mutect2, varscan2
- PCDHA11 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 118/471 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56514278; called by muse, mutect2, varscan2
- PCDHA13 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.139); catalogued as rs868963567, COSV56502477; called by muse, mutect2, varscan2
- PCDHA2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 128/651 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as rs782027744, COSV65366259; called by muse, mutect2, varscan2
- PCDHA3 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV63539394; called by muse, mutect2, varscan2
- PCDHAC1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 131/542 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140626189, COSV53845270; called by muse, mutect2, varscan2
- PCDHB10 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 116/479 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs267600435, COSV53376257; called by muse, mutect2, varscan2
- PCDHB3 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 198/893 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs1563837333, COSV50564880; called by muse, mutect2, varscan2
- PCDHB7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 104/393 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.055); catalogued as rs267600426, COSV50753987; called by muse, mutect2, varscan2
- PCDHGB3 | c.1848del p.F617Sfs*46 | Frame Shift Del (DEL) | VAF 120/528 reads (23%) | catalogued as COSV53916849; called by mutect2, pindel, varscan2
- PCF11 | c.510C>T p.P170= | Splice Region (SNP) | VAF 83/310 reads (27%) | catalogued as rs780581736; called by muse, mutect2, varscan2
- PCLO | c.15307G>A p.G5103R | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61617765; called by muse, mutect2, varscan2
- PCLO | c.13796C>T p.S4599F | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV61616647; called by muse, mutect2, varscan2
- PCLO | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100429511; called by muse, mutect2, varscan2
- PCNX2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 112/467 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as rs776734552; called by muse, mutect2, varscan2
- PDCD1 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 116/634 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV100545446; called by muse, mutect2, varscan2
- PDE6A | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs754762237, COSV54924278; called by muse, mutect2, varscan2
- PDE6C | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs766058431, COSV65114545; called by muse, mutect2, varscan2
- PDK3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 95/406 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs1165981822, COSV64794098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKFB4 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 130/425 reads (31%) | PolyPhen probably damaging (1); catalogued as rs201114950, COSV51682889; called by muse, mutect2, varscan2
- PHF21B | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 105/441 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1279263725, COSV100504013; called by muse, mutect2, varscan2
- PHRF1 | c.3910C>T p.P1304S (on ENST00000264555 / NM_001286581.2; = p.P1303S on NM_020901.4) | Missense Mutation (SNP) | VAF 184/826 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.08); catalogued as rs182522052; called by mutect2, varscan2
- PIAS3 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 154/663 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV100566772; called by muse, mutect2, varscan2
- PIGR | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 137/561 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs973634813, COSV62903226; called by muse, mutect2, varscan2
- PIWIL3 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 79/353 reads (22%) | catalogued as rs201629118, COSV59996790; called by muse, mutect2, varscan2
- PKHD1L1 | c.6857G>A p.G2286E | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314472803, COSV65739940; called by muse, mutect2, varscan2
- PLA1A | c.791T>G p.V264G | Missense Mutation (SNP) | VAF 170/480 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1272275486, COSV56332842; called by muse, mutect2, varscan2
- PLCD1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 117/623 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs766195147; called by muse, mutect2, varscan2
- PLCL2 | c.656C>T p.S219F (on ENST00000615277 / NM_001144382.2; = p.S93F on NM_015184.5) | Missense Mutation (SNP) | VAF 202/578 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67622713; called by muse, mutect2, varscan2
- PLD1 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 166/517 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1338897869; called by muse, mutect2, varscan2
- PLEKHG4 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 174/672 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1351357177; called by muse, mutect2, varscan2
- PLEKHS1 | c.316G>A p.E106K (on ENST00000369310 / NM_182601.1; = p.E112K on NM_024889.5) | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.6); catalogued as COSV63057060; called by muse, mutect2, varscan2
- PLXNA4 | c.3452G>A p.G1151E | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58167151; called by muse, mutect2, varscan2
- PLXNB2 | c.3959C>T p.S1320F | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63781403; called by muse, mutect2, varscan2
- PLXNC1 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV51570565; called by muse, mutect2, varscan2
- PNLIPRP2 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs900194360; called by muse, mutect2, varscan2
- PNLIPRP2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100078017; called by muse, mutect2, varscan2
- PNMA5 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 146/664 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs782518669; called by muse, mutect2, varscan2
- POLR3A | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 109/506 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64931330; called by muse, mutect2, varscan2
- POTEA | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.186); catalogued as rs1347374859; called by muse, mutect2, varscan2
- POTEH | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV100625129; called by muse, mutect2, varscan2
- POTEM | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs1267672814; called by muse, mutect2, varscan2
- PPEF1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62995316; called by muse, mutect2, varscan2
- PPFIA2 | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1316742650, COSV61040678; called by muse, mutect2, varscan2
- PPIP5K1 | c.3656G>A p.G1219E (on ENST00000396923; = p.G1194E on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100288066; called by muse, mutect2, varscan2
- PPP1R12B | c.1851G>A p.R617= | Splice Region (SNP) | VAF 84/337 reads (25%) | catalogued as rs751899270, COSV51786213; called by muse, mutect2, varscan2
- PPP6R1 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 117/480 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs201977593, COSV101336990, COSV101337023; called by muse, mutect2, varscan2
- PRAMEF10 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 74/874 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs201590439; called by muse, mutect2
- PRAMEF4 | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 164/839 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs1240837836; called by muse, mutect2
- PRAMEF4 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 146/389 reads (38%) | catalogued as COSV52437958; called by muse, mutect2, varscan2
- PRB2 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 155/704 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV66984523; called by muse, varscan2
- PRDM16 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755741214; called by muse, mutect2, varscan2
- PRKCQ | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 93/507 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54120707; called by muse, mutect2, varscan2
- PROC | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749500010, CM951009; called by muse, mutect2
- PROS1 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 129/373 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD084192, COSV67776504; called by muse, mutect2, varscan2
- PRR5 | c.298C>T p.R100W (on ENST00000336985 / NM_181333.4; = p.R91W on NM_015366.4) | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201344303; called by muse, mutect2, varscan2
- PRRC2B | c.4097C>T p.S1366F | Missense Mutation (SNP) | VAF 109/500 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770098147; called by muse, mutect2, varscan2
- PSMB5 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 85/413 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs757517791; called by muse, mutect2, varscan2
- PTK2B | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs778098175; called by muse, mutect2, varscan2
- PTPN18 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 128/539 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763988056; called by muse, mutect2, varscan2
- PTPN5 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs748561321, COSV60032927; called by muse, mutect2, varscan2
- PTPRB | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 130/628 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as COSV51741721; called by muse, mutect2
- PTPRQ | c.1082G>A p.G361E (on ENST00000616559; = p.G319E on NM_001145026.2) | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1212862007; called by muse, mutect2, varscan2
- PXDNL | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV62492962, COSV62495546; called by muse, mutect2, varscan2
- RALGPS2 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV62678599; called by muse, mutect2, varscan2
- RAPGEF5 | c.1074G>A p.W358* (on ENST00000401957 / NM_001367602.2; = p.W661* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 57/410 reads (14%) | catalogued as COSV100686500; called by muse, mutect2, varscan2
- RASGRP1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV60364131; called by muse, mutect2, varscan2
- RASSF9 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs369886202; called by muse, mutect2, varscan2
- RBFOX3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 127/609 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs1298625389; called by muse, mutect2, varscan2
- RBMXL2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 138/672 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV60978691; called by muse, mutect2
- RBPJL | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 116/498 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59215751; called by muse, mutect2, varscan2
- RCOR3 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 121/529 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100879562; called by muse, mutect2, varscan2
- REC114 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 125/538 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV99044305; called by muse, mutect2, varscan2
- REEP1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD118424, COSV99382805; called by muse, mutect2
- REG1A | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 51/257 reads (20%) | catalogued as COSV99286852; called by muse, mutect2, varscan2
- RGMB | c.1225C>T p.P409S (on ENST00000513185 / NM_001366508.1; = p.P450S on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/543 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as rs906291400; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RHBDF1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 164/655 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs1429556943; called by muse, mutect2, varscan2
- RHOT2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs374331798; called by muse, mutect2, varscan2
- RIMBP3B | c.4799G>A p.G1600E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380372043; called by mutect2, varscan2
- RIMS1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1479837493, COSV99325862; called by muse, mutect2, varscan2
- RINT1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1440865817, COSV57558742; called by muse, mutect2, varscan2
- RNF112 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs78460530; called by muse, mutect2, varscan2
- RNF17 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV99693984; called by muse, mutect2, varscan2
- RNF213 | c.5189C>T p.S1730F | Missense Mutation (SNP) | VAF 112/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252894994; called by muse, mutect2, varscan2
- RNF31 | c.2644C>T p.R882* | Nonsense Mutation (SNP) | VAF 93/458 reads (20%) | catalogued as COSV60726291; called by muse, mutect2, varscan2
- RNF40 | c.2878C>T p.L960F | Missense Mutation (SNP) | VAF 150/532 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443990246; called by muse, mutect2, varscan2
- RORC | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 126/531 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59093290; called by muse, mutect2, varscan2
- RP1 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 136/549 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs745484028, COSV55109485; called by muse, mutect2, varscan2
- RP1 | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs267601954, COSV55128472; called by muse, mutect2, varscan2
- RP1L1 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 133/578 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66761403; called by muse, varscan2
- RPL10A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 119/455 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV100003606; called by muse, mutect2, varscan2
- RPL13 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 117/470 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as rs1413781698, COSV51951527; called by muse, mutect2, varscan2
- RPS6KA6 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV53126458; called by muse, mutect2, varscan2
- RPS6KL1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 101/453 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63581173; called by muse, mutect2, varscan2
- RTL4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 135/570 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV61206563; called by muse, mutect2, varscan2
- RTTN | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 96/435 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV99733044; called by muse, mutect2, varscan2
- RUNX1T1 | c.1537G>A p.E513K (on ENST00000265814 / NM_001198628.1; = p.E486K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs769977778, COSV56138839, COSV56159248; called by muse, mutect2, varscan2
- RYR2 | c.5024C>T p.A1675V | Missense Mutation (SNP) | VAF 121/575 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV63693225; called by muse, mutect2, varscan2
- RYR2 | c.5422G>A p.D1808N | Missense Mutation (SNP) | VAF 116/568 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764565730, COSV63690938; called by muse, mutect2, varscan2
- RYR2 | c.7076G>A p.R2359Q | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); catalogued as rs727504976, CM071984, COSV63670123, COSV63718901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 116/508 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as rs779196123, COSV66799882; called by muse, mutect2, varscan2
- RYR3 | c.6710G>A p.G2237E | Missense Mutation (SNP) | VAF 108/654 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402878006, COSV63109402, COSV63109651; called by muse, mutect2
- S1PR4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 311/861 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.444); catalogued as rs1406975224; called by muse, mutect2, varscan2
- SALL1 | c.2851G>A p.A951T | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1446359548, COSV51760395; called by muse, mutect2, varscan2
- SCGB1D1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.048); catalogued as COSV60377440; called by muse, mutect2, varscan2
- SCIN | c.1900G>A p.E634K (on ENST00000297029 / NM_001112706.3; = p.E387K on NM_033128.3) | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV51689429; called by muse, mutect2, varscan2
- SCN10A | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 165/498 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.457); catalogued as rs866241905, COSV71860351; called by muse, mutect2, varscan2
- SCN11A | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1423082221, COSV56565185; called by muse, mutect2, varscan2
- SCN3A | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs777791237, COSV51828118; called by muse, mutect2, varscan2
- SCNN1G | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 100/392 reads (26%) | catalogued as CM085691; called by muse, mutect2, varscan2
- SEC14L1 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66725396; called by muse, mutect2, varscan2
- SEC14L3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1401134705, COSV53178730; called by muse, mutect2, varscan2
- SEC14L4 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 98/501 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs372907232; called by muse, mutect2, varscan2
- SERPINB10 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1431358206, COSV53071685; called by mutect2, varscan2
- SETBP1 | c.4652G>A p.G1551E | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as rs1568059354; called by muse, mutect2, varscan2
- SETD1B | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 145/619 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs1205739090; called by muse, mutect2, varscan2
- SFTPA2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 74/461 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340748531; called by muse, mutect2, varscan2
- SH2D3C | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 137/540 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs748580820, COSV59120758; called by muse, mutect2, varscan2
- SHANK2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1555098796; called by muse, mutect2, varscan2
- SHCBP1L | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as COSV62353798, COSV62356283; called by muse, mutect2, varscan2
- SI | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV52275947; called by muse, mutect2, varscan2
- SIGLEC1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294675475, COSV52473177; called by muse, mutect2, varscan2
- SIGLEC12 | c.1361C>T p.S454F (on ENST00000291707 / NM_053003.4; = p.S336F on NM_033329.2) | Missense Mutation (SNP) | VAF 84/441 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs267605619, COSV52460508, COSV52463954; called by muse, mutect2, varscan2
- SIM1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 99/323 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.089); catalogued as COSV53495307; called by muse, mutect2, varscan2
- SLAMF9 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 109/494 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100928108; called by muse, mutect2, varscan2
- SLC10A2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs1054582484; called by muse, mutect2, varscan2
- SLC10A2 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1462240395; called by muse, mutect2, varscan2
- SLC16A5 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 134/531 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV61677099; called by muse, mutect2, varscan2
- SLC17A6 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs759033853; called by muse, mutect2, varscan2
- SLC17A6 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99581415; called by muse, mutect2, varscan2
- SLC26A5 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480136383; called by muse, mutect2, varscan2
- SLC3A1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs762659725, COSV53221808; called by muse, mutect2, varscan2
- SLC45A1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 98/444 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV57101754; called by muse, mutect2, varscan2
- SLC4A8 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768049476; called by muse, mutect2, varscan2
- SLC5A12 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1325514001, COSV101237782; called by muse, mutect2, varscan2
- SLC7A13 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs142181923; called by muse, mutect2, varscan2
- SLCO1B3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148029725; called by muse, mutect2, varscan2
- SLITRK2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 164/670 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as COSV59423570; called by muse, mutect2, varscan2
- SLX4 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs546657275, COSV53567951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCO2 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 72/323 reads (22%) | catalogued as rs1325357696; called by muse, mutect2, varscan2
- SMG6 | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV53965569; called by muse, mutect2, varscan2
- SMOC1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs767492109; called by muse, mutect2, varscan2
- SMOX | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53864472; called by muse, varscan2
- SNRNP70 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 147/717 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs983577380; called by muse, mutect2, varscan2
- SNTG1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV52459237; called by muse, mutect2, varscan2
- SORBS2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs746880419; called by muse, mutect2, varscan2
- SP140 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59454538; called by muse, varscan2
- SPATA16 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 84/471 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.273); catalogued as COSV100651412; called by muse, mutect2, varscan2
- SPATA19 | c.437+1G>A p.X146_splice | Splice Site (SNP) | VAF 72/322 reads (22%) | catalogued as rs1027127732, COSV100141078; called by muse, mutect2, varscan2
- SPATA31A1 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1265341213; called by mutect2, varscan2
- SPATS2L | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV62346850; called by muse, mutect2, varscan2
- SPEF2 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61554497; called by muse, mutect2, varscan2
- SPEG | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 141/627 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56672153; called by muse, mutect2
- SPIC | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV54692238, COSV54692405; called by muse, mutect2, varscan2
- SPOCD1 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 108/444 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1242078896; called by muse, mutect2, varscan2
- SPTA1 | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV63757515; called by muse, mutect2, varscan2
- SQSTM1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs756791819; called by muse, mutect2, varscan2
- ST18 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs775290821, COSV99390608; called by muse, mutect2, varscan2
- ST6GAL2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 96/396 reads (24%) | PolyPhen possibly damaging (0.491); catalogued as rs1335982644, COSV64526291; called by muse, mutect2, varscan2
- ST6GAL2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 139/644 reads (22%) | PolyPhen benign (0); catalogued as COSV64526982; called by muse, mutect2, varscan2
- ST7 | c.1360C>T p.L454F (on ENST00000446490; = p.P531= on NM_018412.4) | Missense Mutation (SNP) | VAF 101/514 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as COSV60641071; called by muse, mutect2, varscan2
- STAB2 | c.6119C>T p.S2040L | Missense Mutation (SNP) | VAF 89/358 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1327618835, COSV66337547; called by muse, mutect2, varscan2
- STK31 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 258/525 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs372548842; called by muse, mutect2, varscan2
- STON1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 75/385 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs868767580; called by muse, mutect2, varscan2
- SVOP | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 132/576 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV54464324; called by muse, mutect2, varscan2
- SVOP | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1425417466; called by muse, mutect2, varscan2
- SYMPK | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs901205986; called by muse, mutect2, varscan2
- SYT4 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765872177, COSV54898386; called by muse, mutect2, varscan2
- TAF1C | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 96/497 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs4150151; called by muse, mutect2, varscan2
- TAMALIN | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1048868453; called by muse, mutect2, varscan2
- TBC1D22B | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1366680242; called by muse, mutect2, varscan2
- TBC1D2B | c.2762G>A p.R921H (on ENST00000300584 / NM_144572.1; = p.A904T on NM_015079.6) | Missense Mutation (SNP) | VAF 101/626 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374617939; called by muse, mutect2, varscan2
- TBR1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 115/525 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs780210539; called by muse, mutect2, varscan2
- TBX20 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 122/893 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV101282336, COSV68785565; called by muse, mutect2, varscan2
- TBX21 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 132/670 reads (20%) | catalogued as rs965811401, COSV51595325; called by muse, mutect2, varscan2
- TBX22 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs750292974, COSV64786590; called by muse, mutect2, varscan2
- TBX4 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 111/579 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53607979; called by muse, mutect2, varscan2
- TCERG1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57036284, COSV57038670; called by muse, mutect2, varscan2
- TCF3 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 110/732 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53646334; called by muse, mutect2, varscan2
- TECRL | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101168380; called by muse, mutect2, varscan2
- TENM1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 111/550 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100949066; called by muse, mutect2, varscan2
- TET3 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 130/605 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1558744538; called by muse, mutect2, varscan2
- TET3 | c.4621G>A p.D1541N | Missense Mutation (SNP) | VAF 118/493 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs1253573709; called by muse, mutect2, varscan2
- THBS4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs747315970, COSV100644208, COSV63468749; called by muse, mutect2, varscan2
- TLR5 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 100/428 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs139394912; called by muse, mutect2, varscan2
- TM6SF2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 102/519 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV99363674; called by muse, mutect2, varscan2
- TMC5 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 100/467 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs1194904446; called by muse, mutect2, varscan2
- TMEM199 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV50228362; called by muse, mutect2, varscan2
- TMEM235 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 138/672 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.22); catalogued as COSV66577180; called by muse, mutect2, varscan2
- TMEM61 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 135/700 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV99054975; called by muse, mutect2, varscan2
- TMEM82 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 131/560 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65387992; called by muse, mutect2, varscan2
- TNF | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 203/927 reads (22%) | catalogued as COSV69305352; called by muse, mutect2, varscan2
- TNFRSF10D | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as rs1449052294; called by muse, mutect2, varscan2
- TNFRSF4 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 115/496 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV64879163; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 147/623 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs112591435; called by muse, mutect2, varscan2
- TOPBP1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs369433427, COSV53432929; called by muse, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TPR | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs368340408; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2, varscan2
- TRANK1 | c.7996C>T p.L2666F | Missense Mutation (SNP) | VAF 103/576 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV100084747; called by muse, mutect2, varscan2
- TRAPPC9 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765644558, COSV66893336; called by muse, varscan2
- TRHDE | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs1018592817, COSV99671313; called by muse, mutect2, varscan2
- TRIM15 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 213/1023 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.247); catalogued as COSV64990119; called by muse, mutect2, varscan2
- TRIM49B | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV60320557; called by muse, mutect2, varscan2
- TRIM9 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 122/483 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs916334873; called by muse, mutect2, varscan2
- TRPC5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 111/534 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53284912; called by muse, mutect2, varscan2
- TSPAN33 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1417040659; called by muse, mutect2, varscan2
- TTC28 | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 125/526 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1263923118; called by muse, mutect2, varscan2
- TTN | c.33175G>A p.E11059K (on ENST00000591111; = p.E10132K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/626 reads (20%) | PolyPhen benign (0.406); catalogued as COSV59983998; called by muse, mutect2, varscan2
- TTN | c.24538C>T p.R8180C (on ENST00000591111; = p.R7253C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/494 reads (25%) | PolyPhen possibly damaging (0.867); catalogued as rs369517119, COSV60243203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12991G>A p.E4331K (on ENST00000591111; = p.E4285K on NM_003319.4) | Missense Mutation (SNP) | VAF 116/476 reads (24%) | catalogued as rs1553936042; ClinVar: not provided / uncertain significance; called by muse, varscan2
- TTN | c.10435G>A p.E3479K (on ENST00000591111; = p.E3433K on NM_003319.4) | Missense Mutation (SNP) | VAF 82/351 reads (23%) | catalogued as COSV100630993; called by muse, mutect2, varscan2
- TTN | c.9812C>T p.S3271F (on ENST00000591111; = p.S3225F on NM_003319.4) | Missense Mutation (SNP) | VAF 110/524 reads (21%) | PolyPhen benign (0.001); catalogued as rs867536098, COSV59891245, COSV60211933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 119/685 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.539); catalogued as COSV53909595; called by muse, mutect2, varscan2
- TTYH2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 120/690 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs139572666; called by muse, mutect2, varscan2
- TUBGCP5 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs267604131; called by muse, mutect2, varscan2
- TWSG1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs200630425, COSV50815683; called by muse, mutect2, varscan2
- TXK | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141539626, COSV51919228; called by muse, mutect2, varscan2
- TXLNA | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 117/517 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1305735583; called by muse, mutect2, varscan2
- TXNDC16 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 113/483 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as rs767805499; called by muse, mutect2, varscan2
- UBE2O | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 101/391 reads (26%) | catalogued as COSV60062411; called by muse, mutect2, varscan2
- UGT3A1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 112/550 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99954252; called by muse, mutect2, varscan2
- ULK1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 127/461 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs1243543133, COSV58857779; called by muse, mutect2, varscan2
- UNC13C | c.5115G>A p.M1705I | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs754267652; called by muse, mutect2, varscan2
- USF3 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 112/559 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1424092653; called by muse, mutect2, varscan2
- USP25 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV53483484; called by muse, mutect2, varscan2
- USP6 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 220/531 reads (41%) | catalogued as rs1450211995, COSV51485370, COSV51496246; called by muse, mutect2, varscan2
- UTP14C | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs202151562; called by muse, mutect2, varscan2
- VAV1 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 73/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771728616; called by muse, mutect2, varscan2
- VPS13C | c.10129G>A p.D3377N (on ENST00000644861 / NM_020821.3; = p.D3334N on NM_017684.5) | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566963998; called by muse, mutect2, varscan2
- VPS8 | c.2029C>T p.R677C (on ENST00000625842 / NM_001349294.1; = p.R675C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs374195614; called by muse, mutect2, varscan2
- VRTN | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 149/551 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV56441591; called by muse, mutect2, varscan2
- VWA3B | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV68243367; called by muse, mutect2, varscan2
- VWDE | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 183/410 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV51721114, COSV51726941; called by muse, mutect2, varscan2
- WDHD1 | c.2342G>T p.C781F | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs149385991; called by muse, mutect2, varscan2
- WFDC3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as COSV54785848; called by muse, mutect2, varscan2
- WNK3 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 101/543 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV63613108; called by muse, mutect2, varscan2
- WNT7B | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 144/615 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372602740; called by muse, mutect2, varscan2
- WWC1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54652110; called by muse, mutect2, varscan2
- XIRP2 | c.6953C>T p.S2318F (on ENST00000628543; = p.S2493F on NM_152381.6) | Missense Mutation (SNP) | VAF 99/437 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs112479318; called by muse, mutect2, varscan2
- XIRP2 | c.9620G>A p.G3207E (on ENST00000628543; = p.G3382E on NM_152381.6) | Missense Mutation (SNP) | VAF 85/413 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99746289; called by muse, mutect2, varscan2
- ZAN | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 154/697 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as rs369072360, COSV61805765; called by muse, mutect2, varscan2
- ZBTB3 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 138/581 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as rs776418672; called by muse, mutect2, varscan2
- ZBTB42 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 147/671 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs756532898; called by muse, mutect2, varscan2
- ZFPM2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 86/459 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752577785, COSV68278632; called by muse, mutect2
- ZFPM2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368018625; called by muse, mutect2, varscan2
- ZFX | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 159/602 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58447225, COSV58447776; called by muse, mutect2, varscan2
- ZNF117 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV51429963; called by muse, mutect2, varscan2
- ZNF208 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.043); catalogued as COSV74192346; called by muse, mutect2
- ZNF208 | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 139/785 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV68108324; called by muse, mutect2, varscan2
- ZNF213 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 164/646 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754437159; called by muse, mutect2, varscan2
- ZNF274 | c.1334C>T p.P445L (on ENST00000610905; = p.P340L on NM_016324.3) | Missense Mutation (SNP) | VAF 116/542 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1479946012; called by muse, mutect2, varscan2
- ZNF347 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 120/577 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as COSV61968415; called by muse, mutect2, varscan2
- ZNF41 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100492364; called by muse, mutect2, varscan2
- ZNF454 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 120/568 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs775513945; called by muse, mutect2, varscan2
- ZNF501 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 98/575 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.796); catalogued as COSV68516177, COSV68516456; called by muse, mutect2, varscan2
- ZNF512B | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 115/540 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs770824372; called by muse, mutect2, varscan2
- ZNF559 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 95/547 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV57836243; called by muse, mutect2, varscan2
- ZNF559 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 78/476 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs377766347; called by muse, mutect2, varscan2
- ZNF560 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 123/710 reads (17%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.916); catalogued as rs148887048; called by muse, mutect2, varscan2
- ZNF585A | c.1226C>T p.S409L (on ENST00000292841 / NM_001288800.2; = p.S354L on NM_152655.3) | Missense Mutation (SNP) | VAF 101/459 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs146470162; called by muse, mutect2, varscan2
- ZNF648 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV60572837; called by muse, mutect2, varscan2
- ZNF648 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 149/595 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs757852320, COSV60569859; called by muse, mutect2, varscan2
- ZNF668 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 154/600 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761144473; called by muse, mutect2, varscan2
- ZNF684 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 128/515 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65519843; called by muse, mutect2, varscan2
- ZNF780B | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55464458; called by muse, mutect2, varscan2
- ZNF786 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV60277572; called by muse, mutect2, varscan2
- ZNF844 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 115/671 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV71518181; called by muse, mutect2, varscan2
- ZSCAN25 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 130/599 reads (22%) | catalogued as rs372780330; called by muse, mutect2, varscan2
- ZSCAN4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 128/541 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755945198; called by muse, mutect2, varscan2
- ABCA1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA7 | c.3970C>T p.P1324S | Missense Mutation (SNP) | VAF 81/510 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCB5 | c.1918G>A p.E640K (on ENST00000404938 / NM_001163941.2; = p.E195K on NM_178559.6) | Missense Mutation (SNP) | VAF 234/513 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ABCC8 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AC011479.1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 122/702 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC100868.1 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 95/625 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ACTN1 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ACTN2 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 125/468 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ACTRT1 | c.874A>T p.N292Y | Missense Mutation (SNP) | VAF 147/605 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ACTRT2 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 124/609 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ADAMTS2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 134/585 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.4991G>A p.G1664E | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRG4 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 155/565 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, varscan2
- ADGRV1 | c.4105G>A p.G1369R | Missense Mutation (SNP) | VAF 125/571 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.12620A>T p.K4207I | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AHI1 | c.2703G>A p.M901I | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AKAP14 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 149/656 reads (23%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AKR1C2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 47/429 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, varscan2
- ALDOB | c.974A>C p.Q325P | Missense Mutation (SNP) | VAF 81/415 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- AMIGO2 | c.1110_1116delinsTC p.L371Qfs*2 | Frame Shift Del (DEL) | VAF 51/425 reads (12%) | called by pindel, varscan2*
- AMMECR1L | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 85/426 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- AMZ1 | c.602-1G>A p.X201_splice | Splice Site (SNP) | VAF 262/552 reads (47%) | called by muse, mutect2, varscan2
- ANK1 | c.3104G>A p.G1035E | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKEF1 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 132/574 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANKK1 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 140/585 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ANKLE1 | c.1139C>T p.S380F (on ENST00000394458; = p.S326F on NM_152363.6) | Missense Mutation (SNP) | VAF 134/698 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ANKRD18A | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD30B | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ANKRD31 | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANO5 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ANO5 | c.1378T>A p.F460I | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO5 | c.1379T>A p.F460Y | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.116); called by muse, varscan2
- ANXA10 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 89/268 reads (33%) | called by muse, mutect2, varscan2
- ANXA8L1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 78/627 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, varscan2
- AP002512.3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AP1B1 | c.2610A>G p.A870= | Splice Region (SNP) | VAF 84/386 reads (22%) | called by muse, mutect2, varscan2
- AP1G1 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- APBB1IP | c.980G>A p.W327* | Nonsense Mutation (SNP) | VAF 67/328 reads (20%) | called by muse, mutect2, varscan2
1,417 further variants in this file (604 protein-altering or splice-affecting, 747 silent, 66 other) are not listed here.
